Gene-level copy-number profile of tumor specimen TARGET-10-PASFLK-09A from TARGET case TARGET-10-PASFLK, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.0 years (4,390 days).
Specimen TARGET-10-PASFLK-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.676ddb2b-d227-58cc-9120-26546b3b442b.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PASFLK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 438 have no estimate.
https://portal.gdc.cancer.gov/files/a8e2b233-814b-4532-ab12-514248c77e5d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 79; copy number 1: 3,693; copy number 2: 54,788; copy number 3: 1,624; copy number 4: 1.

Homozygous deletions (total copy number 0; autosomes only): 79 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,600,662–152,601,086, 1 gene: LCE3C.
- chr7:157,109,980–157,417,439, 7 genes (within-gene range 0–1): AC006967.3, UBE3C, RPS27AP12, AC004898.1, AC004975.1, AC004975.2, DNAJB6.
- chr9:21,201,469–22,455,740, 45 genes: IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.
- chr9:36,572,862–37,465,450, 23 genes (within-gene range 0–1): MELK, AL442063.1, AL450267.2, MIR4475, PAX5, AL450267.1, MIR4540, MIR4476, AL161781.2, AL161781.1, LINC01400, AL512604.3, EBLN3P, AL512604.2, ZCCHC7, Y_RNA, AL512604.1, Y_RNA, RNU6-677P, LINC01627, GRHPR, CHCHD4P3, ZBTB5.
- chr11:4,954,772–4,955,713, 1 gene: OR51A2.
- chr11:55,635,113–55,652,854, 2 genes: OR4P4, OR4S2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,307. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
